Somatic mutation profile of tumor specimen 0DJXPR from CCDI case PBBXGW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.5 years (1,285 days).
Specimen 0DJXPR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4a422320-1d89-4175-b6de-d21562b33bce.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJXRK (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/06681283-85cc-4424-99fb-877489e893be

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Frame Shift Ins 1, Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AK9 | c.2845G>A p.G949R | Missense Mutation (SNP) | VAF 139/1104 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV58146916; called by muse, mutect2, varscan2
- USF3 | c.3407_3408insTGCAAGAGCTACTATATCAGTTTGCTCTTGC p.I1140Tfs*13 | Frame Shift Ins (INS) | VAF 0/716 reads (0%) | called by muse*, mutect2
- SLITRK5 | c.828C>T p.D276= | Silent (SNP) | VAF 389/972 reads (40%) | catalogued as rs566287456; called by muse, mutect2, varscan2
